Somatic mutation profile of tumor specimen MP2PRT-PAWADL-TMP1-A (aliquot MP2PRT-PAWADL-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWADL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,197 days).
Specimen MP2PRT-PAWADL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2caffd85-410d-470b-858c-d7e81fa1436a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWADL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWADL-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e8850a3-334e-44e2-8825-781a7fd85b60

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 24, Silent 12, Nonsense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EN2 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 37/990 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.154); catalogued as rs1378543087; called by muse, mutect2
- HK1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.105); catalogued as COSV53858689; called by muse, mutect2
- HOXD3 | c.139C>A p.H47N | Missense Mutation (SNP) | VAF 191/568 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV50881176; called by muse, mutect2, varscan2
- KRT6C | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 272/606 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs563909878; called by muse, varscan2
- LRP1 | c.10180G>A p.D3394N | Missense Mutation (SNP) | VAF 28/558 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs776972808; called by muse, mutect2
- MAB21L4 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 41/789 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs74779896; called by muse, mutect2
- MITF | c.1051G>A p.V351M (on ENST00000448226 / NM_006722.3; = p.V251M on NM_000248.4) | Missense Mutation (SNP) | VAF 19/705 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271000541; ClinVar: uncertain significance; called by muse, mutect2
- NHSL1 | c.3019G>C p.D1007H | Missense Mutation (SNP) | VAF 20/757 reads (3%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.005); catalogued as rs903348570; called by muse, mutect2
- NPY5R | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV58451456; called by muse, mutect2
- PCDHB16 | c.814G>A p.G272R | Missense Mutation (SNP) | VAF 17/540 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1318451722, COSV53367591; called by muse, mutect2
- PDE2A | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 254/555 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs1278223553; called by muse, mutect2, varscan2
- ZFHX4 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 30/549 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.382); catalogued as COSV51476994; called by muse, mutect2
- ZNF277 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 25/647 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV62463315; called by muse, mutect2
- ANO9 | c.1862C>T p.S621F | Missense Mutation (SNP) | VAF 58/615 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF12 | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CDK15 | c.826G>T p.E276* (on ENST00000652192 / NM_001366386.2; = p.E225* on NM_139158.2) | Nonsense Mutation (SNP) | VAF 136/304 reads (45%) | called by muse, mutect2, varscan2
- CLPSL1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 159/924 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- DNAJC16 | c.1725A>C p.E575D | Missense Mutation (SNP) | VAF 119/425 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406867 del CCCATTCACAGTGTTACAAGCCATAACAAAAA | Missense Mutation (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- LPCAT4 | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 12/334 reads (4%) | called by muse, mutect2
- MS4A2 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 17/297 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- OBSCN | c.14458C>G p.L4820V | Missense Mutation (SNP) | VAF 185/436 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- P4HB | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 53/536 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.584); called by muse, mutect2
- PTPRG | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 42/785 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- RECQL | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGV2 | c.354delinsTCCTC p.*119Pfs*? | Frame Shift Ins (INS) | VAF 66/169 reads (39%) | called by mutect2*, pindel, varscan2*
- USP6NL | c.1610T>G p.L537R | Missense Mutation (SNP) | VAF 264/603 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- ZNF181 | c.1253C>G p.S418* | Nonsense Mutation (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- C4orf19 | c.360G>A p.R120= | Silent (SNP) | VAF 43/737 reads (6%) | called by muse, mutect2
- CACNA1F | c.1989C>A p.L663= | Silent (SNP) | VAF 93/297 reads (31%) | catalogued as COSV59906748; called by muse, mutect2, varscan2
- DIAPH2 | c.360C>T p.N120= | Silent (SNP) | VAF 113/119 reads (95%) | catalogued as rs200157443, COSV61282766; called by muse, mutect2, varscan2
- DYRK1B | c.300C>T p.I100= | Silent (SNP) | VAF 34/727 reads (5%) | catalogued as rs371524346; ClinVar: likely benign; called by muse, mutect2
- GRM1 | c.1944C>T p.L648= | Silent (SNP) | VAF 49/542 reads (9%) | catalogued as rs758245402, COSV51248365, COSV51377423; called by muse, mutect2
- HEATR6 | c.1830A>G p.G610= | Silent (SNP) | VAF 179/422 reads (42%) | called by muse, mutect2, varscan2
- KCND3 | c.447C>T p.D149= | Silent (SNP) | VAF 22/549 reads (4%) | catalogued as rs1553187519, COSV56189540; ClinVar: likely benign; called by muse, mutect2
- PDZD2 | c.6105G>A p.P2035= | Silent (SNP) | VAF 72/719 reads (10%) | catalogued as rs145188510; called by muse, mutect2, varscan2
- PLEKHF1 | c.510G>A p.T170= | Silent (SNP) | VAF 367/819 reads (45%) | catalogued as rs1406314327; called by muse, mutect2, varscan2
- POLR1A | c.372G>A p.L124= | Silent (SNP) | VAF 21/552 reads (4%) | catalogued as rs1158406386; called by muse, mutect2
- RGL3 | c.444G>C p.L148= | Silent (SNP) | VAF 187/413 reads (45%) | called by muse, mutect2, varscan2
- SLC27A5 | c.1134G>C p.V378= | Silent (SNP) | VAF 28/478 reads (6%) | called by muse, mutect2
